Somatic mutation profile of tumor specimen TCGA-06-0168-01A (aliquot TCGA-06-0168-01A-01D-1491-08) from TCGA case TCGA-06-0168, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.6 years (21,776 days).
Specimen TCGA-06-0168-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c1af879-60b5-47ca-a3d2-06fe27e20b56.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0168-10A (Blood Derived Normal), aliquot TCGA-06-0168-10A-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de358404-0967-4b3c-a13f-4e7ce52395c9

The open-access MAF lists 45 somatic variants for this specimen: 30 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 12, Frame Shift Del 2, Intron 1, Nonsense Mutation 1, Splice Site 1, 3'UTR 1, 5'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.*1004A>G | 3'UTR (SNP) | VAF 8/35 reads (23%) | catalogued as rs78311289, CM002967, CM950476, COSV53390625, COSV53407424; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CTIF | c.1624A>G p.M542V | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.138); catalogued as COSV56481722; called by muse, mutect2, varscan2
- CYP4A11 | c.1154C>T p.P385L | Missense Mutation (SNP) | VAF 51/97 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as rs58590117, COSV60222898; called by muse, mutect2, varscan2
- DST | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs183558657, COSV56808337; called by muse, mutect2, varscan2
- EPB42 | c.1270G>T p.G424C (on ENST00000441366 / NM_001114134.2; = p.G454C on NM_000119.3) | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55749066; called by muse, mutect2, varscan2
- FOSB | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 126/366 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs749291738, COSV62278518; called by muse, mutect2, varscan2
- GRM3 | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 71/315 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64469428; called by muse, mutect2, varscan2
- LRP8 | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 107/248 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.266); catalogued as rs759807451, COSV60097353; called by muse, mutect2, varscan2
- MAP3K9 | c.1444C>T p.R482W | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1262960434, COSV67119994; called by muse, varscan2
- MTA3 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 41/113 reads (36%) | catalogued as rs368905145, COSV68133638; called by muse, mutect2, varscan2
- NDST3 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 111/345 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs377531754, COSV56618069; called by muse, mutect2, varscan2
- NDST4 | c.1595C>G p.T532S | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.817); catalogued as COSV52114027; called by muse, mutect2, varscan2
- OR10A3 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs146552050; called by muse, mutect2, varscan2
- OR5A1 | c.232T>C p.S78P | Missense Mutation (SNP) | VAF 73/240 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57376296; called by muse, mutect2, varscan2
- OR8J3 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 56/201 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs201535279; called by muse, mutect2, varscan2
- PCDHA3 | c.1367C>T p.S456L | Missense Mutation (SNP) | VAF 71/198 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs868939985, COSV63540166; called by muse, mutect2, varscan2
- PCDHB13 | c.1643G>A p.R548H | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.243); catalogued as COSV53394764; called by muse, mutect2, varscan2
- PTPRZ1 | c.1108G>C p.D370H | Missense Mutation (SNP) | VAF 65/282 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66433791; called by muse, mutect2, varscan2
- RBBP4 | c.763T>G p.W255G | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65132288; called by muse, mutect2, varscan2
- RRNAD1 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 61/129 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.151); catalogued as rs369382121; called by muse, mutect2, varscan2
- SASH1 | c.1669G>A p.G557R | Missense Mutation (SNP) | VAF 80/286 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769499189, COSV66559322; called by muse, mutect2, varscan2
- SEPTIN10 | c.1349+2_1349+5del p.X450_splice | Splice Site (DEL) | VAF 67/198 reads (34%) | catalogued as rs763052156; called by mutect2, pindel, varscan2
- SGO2 | c.2452A>G p.I818V | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs753461976, COSV63414646; called by muse, mutect2, varscan2
- SLCO5A1 | c.1708T>A p.C570S | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52656723; called by muse, mutect2, varscan2
- SMAGP | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 24/93 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV66312912; called by muse, mutect2, varscan2
- SVEP1 | c.8454C>G p.D2818E | Missense Mutation (SNP) | VAF 77/293 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as COSV52837614; called by muse, mutect2, varscan2
- TRIM51 | c.898A>T p.I300F | Missense Mutation (SNP) | VAF 77/189 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.781); catalogued as COSV55265278; called by muse, mutect2, varscan2
- TRIM51 | c.1165T>A p.C389S | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.035); catalogued as COSV55265302, COSV55271133; called by muse, mutect2, varscan2
- UVRAG | c.988C>G p.P330A | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62102869; called by muse, mutect2, varscan2
- PTEN | c.982_986del p.A328* | Frame Shift Del (DEL) | VAF 53/143 reads (37%) | called by mutect2, pindel, varscan2
- REV1 | c.2432_2436del p.I811Rfs*16 | Frame Shift Del (DEL) | VAF 60/211 reads (28%) | called by mutect2, pindel, varscan2
- AHNAK2 | c.7533G>A p.P2511= | Silent (SNP) | VAF 107/327 reads (33%) | catalogued as rs372687621; called by muse, mutect2, varscan2
- ASB5 | c.69G>A p.S23= | Silent (SNP) | VAF 44/131 reads (34%) | catalogued as rs779312609, COSV56669614; called by muse, mutect2, varscan2
- CACNA1G | c.5859G>A p.L1953= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV61722945; called by muse, mutect2, varscan2
- CDC42BPG | c.618C>T p.N206= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs141134240; called by muse, mutect2, varscan2
- DHX34 | c.2754C>T p.S918= | Silent (SNP) | VAF 42/163 reads (26%) | catalogued as COSV60894870; called by muse, mutect2, varscan2
- GPRASP2 | c.2406T>C p.D802= | Silent (SNP) | VAF 128/254 reads (50%) | catalogued as COSV59990765; called by muse, mutect2, varscan2
- LCE1F | c.114T>C p.P38= | Silent (SNP) | VAF 23/169 reads (14%) | called by muse, mutect2, varscan2
- LYST | c.2712G>A p.V904= | Silent (SNP) | VAF 46/174 reads (26%) | catalogued as COSV67705388; called by muse, mutect2, varscan2
- PNMA8B | c.774C>T p.T258= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs1206393888, COSV66536144; called by mutect2, varscan2
- RTKN2 | c.1533A>G p.K511= | Silent (SNP) | VAF 122/234 reads (52%) | catalogued as COSV59521865; called by muse, mutect2, varscan2
- TRPC4 | c.1632G>A p.T544= | Silent (SNP) | VAF 44/93 reads (47%) | catalogued as rs540496931, COSV58995782, COSV59019937; called by muse, mutect2, varscan2
- USH2A | c.14823C>T p.D4941= | Silent (SNP) | VAF 69/161 reads (43%) | catalogued as COSV56349502; called by muse, mutect2, varscan2
- DOCK8 | chr9:214614 G>T | 5'Flank (SNP) | VAF 14/50 reads (28%) | catalogued as COSV66688033; called by muse, mutect2, varscan2
- OBSCN | c.5138-1741G>A | Intron (SNP) | VAF 15/71 reads (21%) | catalogued as rs767687160; called by muse, mutect2, varscan2
